Somatic mutation profile of cancer-model specimen HCM-CSHL-0379-C18-85C (3D Organoid, passage 4; aliquot HCM-CSHL-0379-C18-85C-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0379-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,410 days).
Specimen HCM-CSHL-0379-C18-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15b28504-3f36-496d-8605-6e7fc20fec06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0379-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0379-C18-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad37e9da-592c-4613-ae32-6d57bfa9e64d

The open-access MAF lists 112 somatic variants for this specimen: 88 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 21, Nonsense Mutation 5, Frame Shift Ins 3, Intron 2, Frame Shift Del 1, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 77/176 reads (44%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 181/346 reads (52%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 3925/4115 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RALA | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 144/479 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1554297905, COSV50049211; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 223/450 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs752634323, COSV51072804, COSV51081870; called by muse, mutect2, varscan2
- ANKRD30A | c.1133del p.G378Efs*19 (on ENST00000611781; = p.G322Efs*19 on NM_052997.2) | Frame Shift Del (DEL) | VAF 160/445 reads (36%) | catalogued as COSV64624129; called by mutect2, pindel, varscan2
- APBA2 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 311/491 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376193947; called by muse, mutect2, varscan2
- BOC | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 152/365 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as rs1029862359, COSV56355168; called by muse, mutect2, varscan2
- BRD2 | c.831dup p.G278Rfs*24 | Frame Shift Ins (INS) | VAF 71/352 reads (20%) | catalogued as rs1474133237; called by mutect2, pindel, varscan2
- CAPN9 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs370370799; called by muse, mutect2, varscan2
- CCDC87 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 228/405 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs199906600, COSV59578459; called by muse, mutect2, varscan2
- CDH12 | c.1409C>T p.T470I | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as COSV101201858; called by muse, mutect2, varscan2
- CLCNKB | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 356/547 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777095700; called by muse, mutect2, varscan2
- CREB5 | c.179C>T p.P60L (on ENST00000357727 / NM_182898.4; = p.P53L on NM_004904.3) | Missense Mutation (SNP) | VAF 89/354 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760077074, COSV63220219; called by muse, mutect2, varscan2
- CRLF2 | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV67493377; called by muse, mutect2
- DEFB106B | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as rs763635136; called by muse, mutect2, varscan2
- DISP3 | c.592A>G p.N198D | Missense Mutation (SNP) | VAF 168/515 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs769299495; called by muse, mutect2, varscan2
- ELFN2 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 263/556 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as rs372217764; called by muse, mutect2, varscan2
- FBXL19 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 124/555 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1442489106; called by muse, mutect2, varscan2
- FBXW10 | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 175/175 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759260883; called by muse, varscan2
- FOXRED2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 133/687 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.111); catalogued as rs1396052370; called by muse, mutect2, varscan2
- GPR137B | c.1017C>A p.F339L | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs373821559, COSV63992300, COSV63992625; called by muse, mutect2, varscan2
- GPR173 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 283/283 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100212124; called by muse, mutect2, varscan2
- HECW1 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 274/847 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764159115, COSV67835274; called by muse, mutect2, varscan2
- HELZ2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 86/470 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs757788400; called by muse, varscan2
- HYDIN | c.7829C>T p.P2610L | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs1371650515; called by muse, mutect2, varscan2
- KCNB2 | c.272G>C p.R91P | Missense Mutation (SNP) | VAF 187/369 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050758; called by muse, mutect2, varscan2
- KCNQ3 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 120/380 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267601778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIFAP3 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs373189946, COSV100846894; called by muse, mutect2, varscan2
- LAMC1 | c.3595C>T p.R1199* | Nonsense Mutation (SNP) | VAF 75/224 reads (33%) | catalogued as COSV51154755, COSV99280014; called by muse, mutect2, varscan2
- LRP1B | c.5093T>C p.L1698P | Missense Mutation (SNP) | VAF 71/366 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67189309; called by muse, mutect2, varscan2
- MEGF6 | c.4364G>A p.R1455H | Missense Mutation (SNP) | VAF 146/431 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs778623137; called by muse, mutect2, varscan2
- MICB | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 397/815 reads (49%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.994); catalogued as rs766185724, COSV52855463; called by muse, mutect2, varscan2
- MXRA5 | c.8095C>T p.R2699C | Missense Mutation (SNP) | VAF 327/342 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54252600; called by muse, mutect2
- OVOL2 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 122/376 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs762166610; called by muse, mutect2, varscan2
- PABPC3 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 77/561 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs142325663; called by muse, mutect2, varscan2
- PCDHB3 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 315/642 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.847); catalogued as rs1554272676; called by muse, mutect2, varscan2
- PCDHGA10 | c.2119G>A p.V707I | Missense Mutation (SNP) | VAF 342/708 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as rs369551410; called by muse, varscan2
- PTPRF | c.4234G>T p.D1412Y | Missense Mutation (SNP) | VAF 206/328 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100740851, COSV100741255; called by muse, mutect2
- PTPRS | c.4661C>T p.A1554V | Missense Mutation (SNP) | VAF 233/343 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1191088838, COSV53620761; called by muse, mutect2, varscan2
- PXDNL | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 241/459 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs768124415, COSV62479981, COSV62493818; called by muse, mutect2, varscan2
- RNGTT | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 127/292 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as COSV55647670; called by muse, mutect2, varscan2
- RYR1 | c.4821G>A p.M1607I | Missense Mutation (SNP) | VAF 150/521 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as rs771870872; called by muse, mutect2, varscan2
- SIX6 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 106/317 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs775987768, COSV59801786; called by muse, mutect2, varscan2
- SLITRK1 | c.870C>A p.F290L | Missense Mutation (SNP) | VAF 151/608 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV65674904; called by muse, mutect2, varscan2
- SPATA31A3 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 163/347 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1426644880; called by muse, mutect2, varscan2
- TAL1 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 96/352 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs778116882; called by muse, mutect2, varscan2
- TAS2R38 | c.764T>C p.F255S | Missense Mutation (SNP) | VAF 73/532 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs781902826; called by muse, mutect2, varscan2
- TCFL5 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 328/536 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.566); catalogued as rs780872850, COSV53896319; called by muse, mutect2, varscan2
- TEKT4 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 305/589 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs114824441, COSV54622572; called by muse, mutect2, varscan2
- THBD | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 290/761 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1186245570; called by muse, mutect2, varscan2
- TMEM200A | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 161/377 reads (43%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs201700503, COSV51648975, COSV99759901; called by muse, mutect2, varscan2
- TMEM71 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs200344505, COSV100785636, COSV63457874; called by muse, mutect2, varscan2
- TPST1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 379/567 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs376840313; called by muse, mutect2, varscan2
- TPX2 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760110966, COSV55920858; called by muse, mutect2, varscan2
- TTN | c.63238G>A p.E21080K (on ENST00000591111; = p.E13656K on NM_003319.4) | Missense Mutation (SNP) | VAF 143/400 reads (36%) | PolyPhen probably damaging (0.994); catalogued as rs374492812; ClinVar: uncertain significance / benign / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- UBP1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs774635168, COSV52144836; called by muse, mutect2, varscan2
- ADAMTS20 | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 100/403 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL4 | c.2422G>T p.V808F | Missense Mutation (SNP) | VAF 99/354 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP13 | c.2369G>C p.S790T | Missense Mutation (SNP) | VAF 72/257 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AMER1 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 358/358 reads (100%) | called by muse, mutect2, varscan2
- ASMT | c.971C>A p.A324D (on ENST00000381229; = p.A352D on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/918 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CCDC144A | c.2445G>T p.K815N | Missense Mutation (SNP) | VAF 50/50 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, varscan2
- CDCP1 | c.1139C>A p.S380Y | Missense Mutation (SNP) | VAF 173/392 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CDK13 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 579/852 reads (68%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CLEC12A | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A3 | c.2362C>A p.Q788K | Missense Mutation (SNP) | VAF 227/438 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EEF1AKMT3 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 16/523 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2
- EFCAB1 | c.271C>A p.H91N | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH3 | c.4419A>T p.K1473N | Missense Mutation (SNP) | VAF 134/352 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GPR25 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 115/344 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HRH3 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 128/480 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ICAM4 | c.360A>C p.K120N | Missense Mutation (SNP) | VAF 239/396 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- IGHJ1 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 291/291 reads (100%) | called by muse, mutect2, varscan2
- KCNA3 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 25/495 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MPV17 | c.456_457insGAAT p.Y153Efs*38 | Frame Shift Ins (INS) | VAF 63/370 reads (17%) | called by mutect2, pindel, varscan2
- MUC16 | c.19861T>C p.S6621P | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.81); called by muse, mutect2
- MYO16 | c.2423A>G p.E808G | Missense Mutation (SNP) | VAF 346/511 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PHLDA1 | c.458_460dup p.E153dup | In Frame Ins (INS) | VAF 158/330 reads (48%) | called by pindel, varscan2
- PPFIA1 | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 112/335 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SOCS7 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 1540/5280 reads (29%) | called by muse, mutect2, varscan2
- TET1 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 124/266 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- TTN | c.53257G>T p.D17753Y (on ENST00000591111; = p.D10329Y on NM_003319.4) | Missense Mutation (SNP) | VAF 168/439 reads (38%) | PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TTN | c.6866T>A p.I2289N (on ENST00000591111; = p.I2243N on NM_003319.4) | Missense Mutation (SNP) | VAF 60/318 reads (19%) | PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TUT7 | c.4040G>T p.C1347F | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- WDR49 | c.644C>A p.T215N (on ENST00000308378 / NM_001366158.1; = p.T556N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/363 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- ZNF521 | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF84 | c.1482dup p.A495Sfs*4 | Frame Shift Ins (INS) | VAF 88/393 reads (22%) | called by mutect2, pindel, varscan2
- AOC1 | c.1899C>T p.C633= | Silent (SNP) | VAF 33/906 reads (4%) | called by muse, mutect2
- ARHGAP35 | c.4179C>T p.S1393= | Silent (SNP) | VAF 109/289 reads (38%) | catalogued as rs201617559; called by muse, mutect2, varscan2
- DLGAP2 | c.633G>A p.Q211= | Silent (SNP) | VAF 406/656 reads (62%) | called by muse, mutect2, varscan2
- EEF1A2 | c.1338C>T p.G446= | Silent (SNP) | VAF 69/434 reads (16%) | catalogued as rs779261770; called by muse, mutect2, varscan2
- FLI1 | c.996C>T p.Y332= | Silent (SNP) | VAF 146/418 reads (35%) | catalogued as rs752016751, COSV55643083; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEPHL1 | c.1221C>T p.N407= | Silent (SNP) | VAF 59/171 reads (35%) | catalogued as rs557012995, COSV59892696; called by muse, mutect2, varscan2
- HIVEP3 | c.666C>T p.C222= | Silent (SNP) | VAF 208/346 reads (60%) | catalogued as rs756968051, COSV56009945; called by muse, mutect2, varscan2
- KCNB2 | c.2436C>T p.D812= | Silent (SNP) | VAF 65/318 reads (20%) | catalogued as rs1456673547, COSV73053168; called by muse, mutect2, varscan2
- KCNH2 | c.546G>A p.S182= | Silent (SNP) | VAF 272/718 reads (38%) | catalogued as rs773030045; called by muse, mutect2, varscan2
- KLHL38 | c.660G>A p.K220= | Silent (SNP) | VAF 38/724 reads (5%) | catalogued as COSV58087757; called by muse, mutect2
- MAGEB6 | c.468G>A p.S156= | Silent (SNP) | VAF 267/268 reads (100%) | catalogued as rs777376582, COSV66871871, COSV66872222; called by muse, mutect2, varscan2
- MUC16 | c.27975C>T p.A9325= | Silent (SNP) | VAF 115/338 reads (34%) | called by muse, mutect2, varscan2
- PCNX2 | c.3258G>A p.K1086= | Silent (SNP) | VAF 18/306 reads (6%) | called by muse, mutect2
- PLEKHN1 | c.1413C>T p.R471= (on ENST00000379409; = p.R419= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 122/400 reads (31%) | catalogued as rs937172119; called by muse, mutect2, varscan2
- RFPL2 | c.738C>T p.D246= | Silent (SNP) | VAF 227/446 reads (51%) | catalogued as rs749206718, COSV99964579; called by muse, mutect2, varscan2
- RYK | c.336C>T p.T112= | Silent (SNP) | VAF 92/264 reads (35%) | called by muse, mutect2, varscan2
- S1PR4 | c.51G>A p.A17= | Silent (SNP) | VAF 212/567 reads (37%) | catalogued as rs763097963; called by muse, mutect2, varscan2
- WDR87 | c.1920C>T p.P640= | Silent (SNP) | VAF 92/271 reads (34%) | called by muse, mutect2, varscan2
- WHRN | c.2499C>T p.G833= | Silent (SNP) | VAF 168/382 reads (44%) | catalogued as rs755304293; called by muse, varscan2
- ZNF467 | c.1167C>T p.C389= | Silent (SNP) | VAF 174/1158 reads (15%) | catalogued as rs1450008804, COSV57373048; called by muse, mutect2, varscan2
- ZNF786 | c.1893C>T p.R631= | Silent (SNP) | VAF 457/682 reads (67%) | catalogued as COSV60277551; called by muse, mutect2, varscan2
- CELF1 | c.-125T>A | 5'UTR (SNP) | VAF 120/306 reads (39%) | called by muse, mutect2, varscan2
- LAMA4 | c.297+2342G>A | Intron (SNP) | VAF 162/380 reads (43%) | catalogued as rs367709337; called by muse, mutect2, varscan2
- WDR90 | c.4312-42C>T | Intron (SNP) | VAF 161/497 reads (32%) | called by muse, mutect2, varscan2
